Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3612, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3612-01A (Primary Tumor).

Diagnosis:

Resected section of colon (rectum) with tumor-free oral and aboral resection margins and the inclusion of an ulcerated, moderately differentiated adenocarcinoma with infiltration of the perimuscular fatty tissue and a solitary regional lymph node metastasis (G2, pT3 L0 V0 locally R0 pN1 [REDACTED]).

Source: NCI Genomic Data Commons file 30ca5238-07e5-4e23-8142-93e83cb3c97a (TCGA-AG-3612.65573346-8277-4269-AA77-97D0F6332F07.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).